Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041122-09A.3 (aliquot TARGET-15-SJMPAL041122-09A.3-01D) from TARGET case TARGET-15-SJMPAL041122, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (486 days).
Specimen TARGET-15-SJMPAL041122-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd669fda-f682-4e18-aa92-cb1d8bed7a4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041122-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041122-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64ef6081-22d4-40c2-9598-cf54eb5c8288

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD7 | c.1796G>T p.R599L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58282894; called by muse, mutect2
- MACROD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs557866799, COSV54026962; called by muse, mutect2, varscan2
- MFNG | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747879329; called by mutect2, varscan2
- ADGRA3 | c.1372del p.M458Wfs*9 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, varscan2
- C1QTNF5 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- COL8A1 | c.2007C>A p.C669* | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- DES | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.878); called by muse, mutect2
- DPH2 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2
- HDX | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HMCN2 | c.1391C>A p.A464D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- LMAN1 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- OSBPL6 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, varscan2
- PKD1L3 | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- SPI1 | c.443_444insGCCCAATG p.E149Pfs*40 | Frame Shift Ins (INS) | VAF 22/53 reads (42%) | called by pindel, varscan2
- TSPAN17 | c.158C>A p.S53* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- CACNG7 | c.141C>A p.T47= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- FLACC1 | c.1248A>G p.E416= | Silent (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3960C>A p.G1320= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- HMMR | c.24G>A p.L8= | Silent (SNP) | VAF 47/122 reads (39%) | called by muse, mutect2, varscan2
- PPP2R5D | c.292C>A p.R98= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV57839103; called by mutect2, varscan2
- CLSTN3 | c.2528-580C>A | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- HEXD | c.982+151C>A | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
